Somatic mutation profile of tumor specimen MP2PRT-PASTUZ-TMP1-A (aliquot MP2PRT-PASTUZ-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PASTUZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,456 days).
Specimen MP2PRT-PASTUZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) baba81b7-af32-4f7d-bf53-25c7c7e56187.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASTUZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASTUZ-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b0e80723-68b8-40f0-8f76-020781174c77

The open-access MAF lists 31 somatic variants for this specimen: 22 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 8, Nonsense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CALHM2 | c.946G>A p.V316M | Missense Mutation (SNP) | VAF 110/251 reads (44%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs1306164523; called by muse, mutect2, varscan2
- KCNV1 | c.868C>G p.L290V | Missense Mutation (SNP) | VAF 30/302 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as COSV52087622; called by muse, mutect2
- KSR2 | c.1214G>A p.R405K | Missense Mutation (SNP) | VAF 27/230 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.684); catalogued as rs752182809; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2
- PLXNB3 | c.3580G>A p.E1194K | Missense Mutation (SNP) | VAF 14/434 reads (3%) | SIFT tolerated (0.84); PolyPhen benign (0.036); catalogued as rs781988597; called by muse, mutect2
- PTPRS | c.4976G>A p.R1659H | Missense Mutation (SNP) | VAF 95/261 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs749770933, COSV53619560; called by muse, mutect2, varscan2
- RYR3 | c.5287G>C p.E1763Q | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV66806187; called by muse, mutect2
- SEMA5A | c.124G>T p.E42* | Nonsense Mutation (SNP) | VAF 58/160 reads (36%) | catalogued as COSV101227302, COSV66800825; called by muse, mutect2, varscan2
- TNFSF4 | c.404T>C p.V135A | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.226); catalogued as COSV56056901; called by muse, mutect2, varscan2
- XPO5 | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1366410108, COSV54828519; called by muse, mutect2, varscan2
- ZC3H4 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 15/357 reads (4%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.23); catalogued as COSV53410767, COSV53417444; called by muse, mutect2
- ATM | c.8712G>C p.E2904D | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BCORL1 | c.2566C>T p.Q856* | Nonsense Mutation (SNP) | VAF 65/434 reads (15%) | called by muse, mutect2, varscan2
- CENPE | c.8027G>C p.G2676A | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- COL22A1 | c.4376C>G p.P1459R | Missense Mutation (SNP) | VAF 76/148 reads (51%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- DGKK | c.627G>A p.M209I | Missense Mutation (SNP) | VAF 105/372 reads (28%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- ECT2L | c.1808A>G p.N603S | Missense Mutation (SNP) | VAF 82/208 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2
- FAM172A | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.091); called by muse, mutect2
- IGLV4-69 | chr22:22031468 ATTCACA>TTGGGG | Missense Mutation (DEL) | VAF 47/111 reads (42%) | called by pindel, varscan2*
- KITLG | c.40C>G p.L14V | Missense Mutation (SNP) | VAF 7/143 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MOBP | c.281C>T p.P94L (on ENST00000420739; = p.P118L on NM_001278322.2) | Missense Mutation (SNP) | VAF 144/501 reads (29%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- THOC1 | c.1782G>C p.M594I | Missense Mutation (SNP) | VAF 10/259 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0.111); called by muse, mutect2
- ADGRG4 | c.4644G>A p.L1548= | Silent (SNP) | VAF 58/239 reads (24%) | called by muse, mutect2, varscan2
- FAM171B | c.81C>T p.P27= | Silent (SNP) | VAF 88/318 reads (28%) | called by muse, varscan2
- GLP2R | c.1257C>T p.F419= | Silent (SNP) | VAF 25/107 reads (23%) | catalogued as COSV52324428; called by muse, mutect2, varscan2
- MARCHF1 | c.375C>G p.L125= (on ENST00000274056; = p.L108= on NM_017923.4) | Silent (SNP) | VAF 9/193 reads (5%) | catalogued as COSV99920715; called by muse, mutect2
- PRKRA | c.105G>A p.P35= | Silent (SNP) | VAF 90/259 reads (35%) | catalogued as rs751447432, COSV57870159; called by muse, mutect2, varscan2
- RGSL1 | c.810C>G p.L270= | Silent (SNP) | VAF 7/223 reads (3%) | called by muse, mutect2
- SLC11A1 | c.546C>T p.F182= | Silent (SNP) | VAF 54/229 reads (24%) | called by muse, mutect2, varscan2
- SLC26A6 | c.1728G>A p.K576= | Silent (SNP) | VAF 10/174 reads (6%) | catalogued as COSV56572176; called by muse, mutect2
- ZFPM1 | c.402+2045G>A | Intron (SNP) | VAF 75/187 reads (40%) | catalogued as rs1292809692; called by muse, mutect2, varscan2
